Somatic mutation profile of tumor specimen TCGA-G7-6790-01A (aliquot TCGA-G7-6790-01A-11D-1961-08) from TCGA case TCGA-G7-6790, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.0 years (21,169 days).
Specimen TCGA-G7-6790-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81e5291f-f9a9-420e-9c0b-8432353bb09c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6790-10A (Blood Derived Normal), aliquot TCGA-G7-6790-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e290bd-f462-40da-8608-79161dd6aa02

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 2, Intron 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.1292T>C p.L431P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55457999; called by muse, varscan2
- ACO1 | c.2419A>T p.N807Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59379406, COSV59380349; called by muse, mutect2, varscan2
- ACSL1 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs767829093, COSV55662206; called by muse, mutect2
- ADAMTS13 | c.1813G>C p.V605L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63021004; called by muse, mutect2, varscan2
- ADARB1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs774995629, COSV62343879; called by muse, mutect2, varscan2
- ADCY1 | c.2820T>C p.A940= | Splice Region (SNP) | VAF 49/96 reads (51%) | catalogued as COSV52033696; called by muse, mutect2, varscan2
- ADNP | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62425127; called by muse, mutect2, varscan2
- AGAP2 | c.3304G>A p.A1102T (on ENST00000547588 / NM_001122772.2; = p.A746T on NM_014770.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV57727873; called by muse, mutect2, varscan2
- APOL4 | c.47T>C p.V16A (on ENST00000352371 / NM_145660.2; = p.V13A on NM_030643.4) | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60495740; called by muse, mutect2, varscan2
- C3 | c.1706A>C p.Q569P | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55572013, COSV55578297; called by muse, mutect2, varscan2
- CCDC70 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV54430104; called by muse, mutect2, varscan2
- CEP250 | c.6164A>G p.Q2055R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV61169601; called by muse, mutect2, varscan2
- CRKL | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62883142, COSV62883602; called by muse, mutect2, varscan2
- CTNNA1 | c.2191C>T p.R731* | Nonsense Mutation (SNP) | VAF 73/180 reads (41%) | catalogued as rs1401839892, COSV57073200; called by muse, mutect2, varscan2
- FCER2 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60916263; called by muse, mutect2, varscan2
- FRYL | c.2621C>A p.A874E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV51945528; called by muse, varscan2
- FRYL | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV51945537; called by muse, varscan2
- GRHL1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61407783; called by muse, mutect2, varscan2
- HNF1A | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as CM056410, COSV56567016; called by muse, mutect2, varscan2
- HNRNPK | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV61089370; called by muse, mutect2, varscan2
- ITGA11 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100242372, COSV59877065; called by muse, mutect2, varscan2
- JAK1 | c.1105T>A p.F369I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61090440; called by muse, mutect2, varscan2
- JMJD1C | c.2710T>A p.W904R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59514297; called by muse, mutect2, varscan2
- KMT2D | c.7318G>A p.V2440I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); catalogued as rs375114492; called by muse, mutect2, varscan2
- KMT2E | c.785T>G p.I262S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV57572557; called by muse, mutect2, varscan2
- KTN1 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV68023315; called by muse, mutect2, varscan2
- LRRC4C | c.1568T>G p.M523R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53423783; called by muse, mutect2, varscan2
- MAU2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.51); catalogued as COSV53234998; called by muse, mutect2, varscan2
- MISP | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53119691; called by muse, mutect2
- MYH13 | c.2894T>A p.L965* | Nonsense Mutation (SNP) | VAF 64/100 reads (64%) | catalogued as COSV52826568; called by muse, mutect2, varscan2
- MYH14 | c.2327A>G p.N776S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV51815515; called by muse, varscan2
- MYH8 | c.2330A>G p.E777G | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV67963925; called by muse, mutect2, varscan2
- NBAS | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55719515; called by muse, mutect2, varscan2
- NLRP8 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52586404, COSV52593215; called by muse, mutect2, varscan2
- NTAQ1 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV54874402; called by muse, mutect2, varscan2
- PCDH8 | c.2959T>A p.F987I | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58812257; called by muse, mutect2, varscan2
- PODXL2 | c.728T>A p.L243* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV61065243; called by muse, mutect2, varscan2
- PPP4R3B | c.1208T>C p.M403T | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV55404061; called by muse, mutect2, varscan2
- RDH5 | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745435816, COSV57676331; called by muse, mutect2, varscan2
- RUFY4 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV60247340; called by muse, mutect2, varscan2
- RYR1 | c.7244G>A p.R2415Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.44); catalogued as rs201584482, COSV62095532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAPER | c.3643G>A p.V1215M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57739170; called by muse, mutect2, varscan2
- SHROOM3 | c.4360C>A p.L1454M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV56028024; called by muse, mutect2, varscan2
- SLC39A8 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV63222483; called by muse, mutect2, varscan2
- SLC6A17 | c.1576T>A p.Y526N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58992698; called by muse, mutect2, varscan2
- TRIM46 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV55278720; called by muse, varscan2
- TTN | c.2111C>G p.T704R (on ENST00000591111; = p.T658R on NM_003319.4) | Missense Mutation (SNP) | VAF 49/91 reads (54%) | PolyPhen probably damaging (0.998); catalogued as COSV60010803; called by muse, mutect2, varscan2
- XRN1 | c.1769G>C p.R590T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV53810844, COSV99377803; called by muse, mutect2, varscan2
- XYLT1 | c.1290G>C p.R430S | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54482914; called by muse, mutect2, varscan2
- ZBTB45 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.939); catalogued as COSV54019157; called by muse, mutect2, varscan2
- BPHL | c.125_145del p.A42_G48del | In Frame Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel
- DBX1 | c.845del p.P282Rfs*? | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- F5 | c.3411_3412dup p.M1138Kfs*34 | Frame Shift Ins (INS) | VAF 65/243 reads (27%) | called by mutect2, pindel, varscan2
- FMO1 | c.182_187delinsTA p.N61Ifs*40 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by pindel, varscan2*
- GREB1 | c.364del p.V122Sfs*54 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- NLK | c.636del p.F212Lfs*10 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RC3H1 | c.2584_2585del p.T862Qfs*2 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- RPL10A | c.276dup p.L93Tfs*5 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- CAPS | c.78G>T p.L26= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV50381242; called by muse, mutect2, varscan2
- CMTR1 | c.1911A>G p.L637= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs749091231, COSV65090193; called by muse, mutect2, varscan2
- CNTLN | c.1590G>A p.K530= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52075732; called by muse, mutect2, varscan2
- COL14A1 | c.1836A>T p.S612= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52852931; called by muse, mutect2, varscan2
- EPB41L1 | c.1098C>A p.V366= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV52437053, COSV52438731; called by muse, mutect2, varscan2
- FAM71B | c.1182A>T p.A394= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV57228788; called by muse, mutect2, varscan2
- FRYL | c.2622A>G p.A874= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV51945521; called by muse, varscan2
- GAD1 | c.415C>T p.L139= | Silent (SNP) | VAF 59/115 reads (51%) | catalogued as COSV60152182; called by muse, mutect2, varscan2
- H3C1 | c.291C>T p.C97= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs771690950, COSV55119273; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.783A>G p.E261= | Silent (SNP) | VAF 54/179 reads (30%) | catalogued as rs1158907264, COSV59011764; called by muse, mutect2, varscan2
- PNCK | c.285T>A p.G95= (on ENST00000340888 / NM_001366975.1; = p.G178= on NM_001039582.3) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV61743585, COSV61743920; called by muse, mutect2, varscan2
- SPTLC1 | c.27T>A p.V9= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV52763842; called by muse, mutect2, varscan2
- SRARP | c.120G>C p.T40= | Silent (SNP) | VAF 106/408 reads (26%) | catalogued as COSV61497766; called by muse, mutect2, varscan2
- STAC2 | c.1197G>A p.K399= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV61065361; called by muse, mutect2, varscan2
- TTN | c.83589T>C p.D27863= (on ENST00000591111; = p.D20439= on NM_003319.4) | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV60010768; called by muse, mutect2, varscan2
- ZNF804A | c.945A>G p.Q315= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as COSV56446009; called by muse, mutect2, varscan2
- EPSTI1 | c.949-718G>A | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as rs1209462732, COSV58045124; called by muse, mutect2, varscan2
- EPSTI1 | c.949-719A>T | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as COSV58045131; called by muse, mutect2, varscan2
